Somatic mutation profile of tumor specimen 0DLX55 from CCDI case PBBYKS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 15.1 years (5,517 days).
Specimen 0DLX55: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c6be651-1225-434c-9246-3d17a2e2c8fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLX4I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd1d06c2-5ac5-4f6d-8942-2c2c38b6f5f3

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 364/1031 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- KCNK15 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 163/497 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1379093312, COSV65719796; called by muse, mutect2, varscan2
- NAA15 | c.1271T>C p.I424T | Missense Mutation (SNP) | VAF 86/1277 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as rs1382149919; called by muse, mutect2
- ADH1B | c.522C>T p.G174= | Silent (SNP) | VAF 72/1482 reads (5%) | called by muse, mutect2
- SNX20 | c.813C>T p.D271= | Silent (SNP) | VAF 131/377 reads (35%) | catalogued as rs750413433, COSV56057562; called by muse, mutect2, varscan2
- KIF9 | c.1515-15C>T | Intron (SNP) | VAF 86/493 reads (17%) | catalogued as rs777885656; called by muse, mutect2, varscan2
- ORMDL2 | c.-1-63T>C | Intron (SNP) | VAF 88/274 reads (32%) | catalogued as rs1273415740; called by muse, mutect2, varscan2
